Somatic mutation profile of tumor specimen TCGA-AA-3949-01A (aliquot TCGA-AA-3949-01A-01W-0995-10) from TCGA case TCGA-AA-3949, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AA-3949-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ceb6e5b-03b0-48f4-9b8f-a46d0694c0b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3949-10A (Blood Derived Normal), aliquot TCGA-AA-3949-10A-01W-1982-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21030d58-debe-42aa-b940-e26994487097

The open-access MAF lists 1,374 somatic variants for this specimen: 1,046 protein-altering or splice-affecting, 296 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 797, Silent 296, Frame Shift Del 141, Nonsense Mutation 48, Frame Shift Ins 29, Splice Site 19, Intron 12, RNA 9, Splice Region 9, 3'Flank 5, In Frame Del 2, 3'UTR 2.

Variants (750 of 1,374; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as rs78001248, CM143764, COSV100609536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs141764916, CM050996; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADARB1 | c.2165C>T p.A722V (on ENST00000360697 / NM_001346687.2; = p.A682V on NM_001112.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1323703791, COSV62345168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALX4 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 196/734 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs104894193, CM010011, COSV61326325; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.2938C>T p.R980* | Nonsense Mutation (SNP) | VAF 32/390 reads (8%) | catalogued as rs199422151, CM092391, COSV54133463, COSV54134529; ClinVar: pathogenic; called by muse, mutect2
- BMPR2 | c.1371del p.K457Nfs*17 | Frame Shift Del (DEL) | VAF 31/289 reads (11%) | catalogued as rs1085307340; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDC73 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 254/857 reads (30%) | catalogued as rs886041158, CM101406, COSV100813909, COSV66467992; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 477/2113 reads (23%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- GJB1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1555937233, CM081653, CM970670, COSV100661308; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 43/217 reads (20%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PRDM14 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 64/345 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762086448, COSV52571818; called by muse, mutect2, varscan2
- RYR2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1060500142, CM056388, COSV63670229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 36/176 reads (20%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by pindel, varscan2
- TBX22 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs104894943, CM013049, COSV64785482; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 46/174 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WARS2 | c.325del p.S109Afs*15 | Frame Shift Del (DEL) | VAF 84/383 reads (22%) | catalogued as rs1253426801; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs369574498; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 48/183 reads (26%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA13 | c.11978T>C p.M3993T | Missense Mutation (SNP) | VAF 121/545 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV101447255; called by muse, mutect2, varscan2
- ABCA8 | c.101G>T p.W34L | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV99287019; called by muse, mutect2, varscan2
- ABCB8 | c.1034G>A p.R345H (on ENST00000297504 / NM_001282291.2; = p.R328H on NM_007188.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778422625, COSV52504302; called by muse, mutect2, varscan2
- ABCC11 | c.2744C>A p.P915Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100750968; called by muse, mutect2, varscan2
- ABCC12 | c.3805C>T p.R1269* | Nonsense Mutation (SNP) | VAF 187/741 reads (25%) | catalogued as rs989536317, COSV100253329; called by muse, mutect2, varscan2
- ABCC3 | c.3320G>A p.S1107N | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1383403640, COSV99559922; called by muse, mutect2, varscan2
- ABR | c.2099C>T p.A700V (on ENST00000302538 / NM_021962.5; = p.A663V on NM_001092.5) | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99348688; called by muse, mutect2, varscan2
- AC090517.4 | c.1783del p.S595Vfs*7 | Frame Shift Del (DEL) | VAF 466/1639 reads (28%) | catalogued as rs1157171684; called by mutect2, varscan2
- ACAP1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs778742775, COSV50139602; called by muse, mutect2, varscan2
- ACER1 | c.662T>C p.M221T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100034136; called by muse, mutect2, varscan2
- ACSL1 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 95/1180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99861012; called by muse, mutect2
- ACSS3 | c.586A>C p.S196R | Missense Mutation (SNP) | VAF 125/414 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99699529; called by muse, mutect2, varscan2
- ACTRT1 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 107/496 reads (22%) | catalogued as COSV100947773; called by muse, mutect2, varscan2
- ACVR1 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 74/799 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.289); catalogued as COSV99718163; called by muse, mutect2
- ACVR2A | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 59/666 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as rs1289533816, COSV99605210; called by muse, mutect2
- ACVR2B | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100754428; called by muse, mutect2, varscan2
- ADAM12 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV64107225; called by muse, mutect2
- ADAMTS12 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV61277509; called by muse, mutect2, varscan2
- ADAMTS16 | c.2010C>A p.Y670* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56996354; called by muse, mutect2
- ADAMTS17 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs756808653, COSV51493548; called by muse, mutect2, varscan2
- ADAMTS2 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1252240288, COSV52374485; called by muse, mutect2, varscan2
- ADARB2 | c.1467del p.C490Vfs*61 | Frame Shift Del (DEL) | VAF 35/147 reads (24%) | catalogued as COSV67221947; called by mutect2, pindel, varscan2
- ADCY2 | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 92/330 reads (28%) | catalogued as COSV57872118; called by muse, mutect2, varscan2
- ADCY3 | c.2055+2T>C p.X685_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99569166; called by muse, mutect2, varscan2
- ADCY4 | c.2121G>T p.W707C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100156890; called by muse, mutect2
- ADCY8 | c.2939C>A p.A980D | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.474); catalogued as COSV99652514; called by muse, mutect2, varscan2
- ADGRL2 | c.1568C>A p.S523* | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | catalogued as COSV54688710, COSV99591799; called by muse, mutect2, varscan2
- ADRA1A | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372408; called by mutect2, varscan2
- AFDN | c.3820C>T p.R1274C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); catalogued as rs768477295, COSV60057616; called by muse, mutect2, varscan2
- AFF2 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV100651299; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | catalogued as COSV58317085; called by mutect2, pindel
- AGGF1 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV57227735; called by muse, mutect2, varscan2
- AGO1 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100940932; called by muse, mutect2, varscan2
- AGO3 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99869466; called by muse, mutect2, varscan2
- AHCTF1 | c.2401G>A p.G801S (on ENST00000366508; = p.G775S on NM_015446.5) | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs879064644, COSV100404488; called by muse, mutect2
- AHRR | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs762929753, COSV100328048; called by muse, mutect2, varscan2
- AKAP6 | c.1859T>C p.V620A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV99804758; called by muse, mutect2, varscan2
- AKAP8 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762759792, COSV54102350; called by muse, varscan2
- AKR1B1 | c.781A>T p.I261F | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99605431; called by muse, mutect2
- ALAD | c.932-2A>G p.X311_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | catalogued as COSV99475078; called by muse, mutect2, varscan2
- ALDOB | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100878931, COSV66397757; called by muse, mutect2, varscan2
- AMN | c.42C>T p.C14= | Splice Region (SNP) | VAF 16/44 reads (36%) | catalogued as rs747910380, COSV54487830; called by muse, mutect2
- AMPD3 | c.1134+2T>C p.X378_splice (on ENST00000396553 / NM_001025389.2; = p.X387_splice on NM_000480.3) | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101158271; called by mutect2, varscan2
- ANK3 | c.12687-1G>T p.X4229_splice (on ENST00000280772 / NM_001320874.2; = p.X853_splice on NM_001149.3) | Splice Site (SNP) | VAF 13/234 reads (6%) | catalogued as COSV99782615; called by muse, mutect2
- ANKRD24 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs768524091, COSV99518211; called by muse, mutect2, varscan2
- ANKRD6 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs747899705, COSV100329845; called by muse, mutect2, varscan2
- ANO1 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100797527; called by muse, mutect2, varscan2
- ANO4 | c.1379A>G p.D460G (on ENST00000392977 / NM_001286615.2; = p.D425G on NM_178826.4) | Missense Mutation (SNP) | VAF 339/1743 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as COSV100153921; called by muse, mutect2, varscan2
- ANXA5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.298); catalogued as rs1438608818, COSV99634719; called by muse, mutect2
- APCDD1L | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1273763703, COSV64487943; called by muse, mutect2, varscan2
- APOBEC3G | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.807); catalogued as rs767773347, COSV101349117; called by muse, mutect2, varscan2
- AQP4 | c.5G>C p.S2T | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV67219525; called by muse, mutect2, varscan2
- AQP5 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776856913, COSV99527555; called by muse, varscan2
- ARAP3 | c.3278A>G p.D1093G | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99500343; called by muse, mutect2
- ARHGAP28 | c.1258T>G p.F420V (on ENST00000383472 / NM_001366230.1; = p.F261V on NM_001010000.3) | Missense Mutation (SNP) | VAF 101/466 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99151507; called by muse, mutect2, varscan2
- ARHGAP6 | c.1235G>T p.R412M | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100273607; called by muse, mutect2
- ARHGDIB | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 222/1086 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV99967428; called by muse, mutect2, varscan2
- ARHGEF10 | c.2944G>A p.A982T (on ENST00000398564; = p.A957T on NM_014629.4) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100035720; called by muse, mutect2, varscan2
- ARHGEF2 | c.421C>A p.R141S (on ENST00000361247 / NM_001162383.2; = p.R114S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100561250; called by muse, mutect2, varscan2
- ARL6IP5 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1362925268, COSV56235570, COSV99833046; called by muse, mutect2, varscan2
- ARX | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100984087; called by muse, mutect2, varscan2
- ASPM | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750015604, COSV54130724; called by mutect2, varscan2
- ASPSCR1 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100145050; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | catalogued as rs768611141; called by mutect2, pindel
- ATF6 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV100909526; called by muse, mutect2
- ATG2B | c.5761A>G p.I1921V | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV99952266; called by muse, mutect2
- ATP10D | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906226; called by muse, mutect2, varscan2
- AVPR2 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs368306347, COSV61686969; called by muse, mutect2, varscan2
- AVPR2 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100509688; called by muse, mutect2, varscan2
- AWAT1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs766687052, COSV65738218; called by muse, mutect2, varscan2
- AZIN2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs144776558; called by muse, mutect2, varscan2
- BCAR3 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 60/690 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs1206172281, COSV53071340; called by muse, mutect2
- BCL2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1273284492, COSV100385998; called by muse, mutect2, varscan2
- BCLAF1 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100787080; called by muse, mutect2, varscan2
- BICRA | c.3328G>A p.A1110T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.576); catalogued as COSV67603923; called by muse, mutect2
- BICRAL | c.2534A>G p.H845R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.023); catalogued as COSV100018544; called by muse, mutect2, varscan2
- BIN1 | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99388637; called by muse, mutect2
- BIN2 | c.216A>G p.K72= | Splice Region (SNP) | VAF 84/341 reads (25%) | catalogued as COSV99909754; called by muse, mutect2, varscan2
- BLK | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs111642844, COSV52049925, COSV99377682; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMS1 | c.2660G>A p.R887H | Missense Mutation (SNP) | VAF 132/626 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760627253, COSV100996838; called by muse, mutect2, varscan2
- BOD1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99603542; called by muse, mutect2, varscan2
- BORCS6 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1470909913, COSV101198035; called by muse, mutect2, varscan2
- BPIFB3 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 133/419 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs766380597, COSV64956947; called by muse, mutect2, varscan2
- BRAT1 | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 181/197 reads (92%) | catalogued as COSV100500714; called by muse, mutect2, varscan2
- BRD1 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99350364; called by muse, mutect2, varscan2
- BRD4 | c.3686G>A p.R1229H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99651492; called by muse, mutect2, varscan2
- BRINP2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs368347121; called by muse, mutect2, varscan2
- BRPF3 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326221; called by muse, mutect2
- BRWD3 | c.3418del p.A1140Lfs*42 | Frame Shift Del (DEL) | VAF 45/376 reads (12%) | catalogued as COSV100956344; called by pindel, varscan2
- BUB1B | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99807368; called by muse, mutect2, varscan2
- C1orf100 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100353504; called by muse, mutect2, varscan2
- C2CD2 | c.720+2T>C p.X240_splice | Splice Site (SNP) | VAF 69/244 reads (28%) | catalogued as COSV100298445; called by muse, mutect2, varscan2
- C3 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs373511900, CM165196; called by muse, mutect2, varscan2
- C7orf31 | c.1498A>G p.T500A | Missense Mutation (SNP) | VAF 47/467 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99384196; called by muse, mutect2, varscan2
- CA10 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 376/689 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53362047, COSV53371994; called by muse, mutect2, varscan2
- CACNA1D | c.1591G>A p.V531I (on ENST00000350061 / NM_001128840.3; = p.V551I on NM_000720.4) | Missense Mutation (SNP) | VAF 28/515 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs199772983, COSV99858612; called by muse, mutect2
- CACNG7 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1182538710, COSV99712334, COSV99712342; called by muse, mutect2, varscan2
- CAD | c.3201G>T p.E1067D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV53032185; called by muse, mutect2, varscan2
- CARMIL1 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV61517172; called by muse, mutect2, varscan2
- CCDC120 | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100900718; called by muse, mutect2
- CCDC120 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs782570114, COSV100900719; called by muse, mutect2, varscan2
- CCDC158 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 64/851 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs759046733, COSV66355431; called by muse, mutect2
- CCDC17 | c.864G>T p.R288S | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99322792; called by muse, mutect2, varscan2
- CCDC24 | c.319T>C p.W107R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV100530976; called by muse, mutect2
- CCDC33 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264007862, COSV99173569; called by muse, mutect2, varscan2
- CCDC73 | c.1202A>T p.N401I | Missense Mutation (SNP) | VAF 133/506 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV100068393; called by muse, mutect2, varscan2
- CCDC80 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs771980493, COSV52814888; called by muse, mutect2
- CCNYL1 | c.803A>G p.D268G (on ENST00000295414 / NM_001330218.2; = p.D198G on NM_152523.2) | Missense Mutation (SNP) | VAF 35/343 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99776100; called by muse, mutect2, varscan2
- CCT5 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725608; called by muse, mutect2
- CCT5 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs768768696, COSV54724123; called by muse, mutect2, varscan2
- CD200R1L | c.661T>A p.S221T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as COSV68004532; called by muse, mutect2, varscan2
- CD58 | c.629-1G>T p.X210_splice | Splice Site (SNP) | VAF 21/252 reads (8%) | catalogued as COSV104423290, COSV65665390; called by muse, mutect2
- CD74 | c.299-1G>T p.X100_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99154328; called by muse, mutect2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs762805003; called by mutect2, pindel
- CDC14A | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 32/656 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100326039; called by muse, mutect2
- CDC25C | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV100086936; called by muse, mutect2, varscan2
- CDC42EP4 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758557269, COSV100232005; called by muse, mutect2, varscan2
- CDC73 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 164/633 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV66464849; called by muse, mutect2, varscan2
- CDH11 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 161/462 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as rs1347469388, COSV99219913; called by muse, mutect2, varscan2
- CDH2 | c.1894C>G p.P632A | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV99063416; called by muse, mutect2, varscan2
- CDH20 | c.1619A>G p.N540S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV99406639; called by muse, mutect2, varscan2
- CDH6 | c.2069G>T p.R690M | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99035134, COSV99418194; called by muse, mutect2, varscan2
- CDH8 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1034179462, COSV54902001; called by muse, mutect2
- CDK13 | c.2460G>T p.Q820H | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476141; called by muse, mutect2, varscan2
- CDK16 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs756986406, COSV99331999; called by muse, mutect2, varscan2
- CDYL | c.1582A>G p.T528A (on ENST00000328908 / NM_001368125.1; = p.T474A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100190226; called by muse, mutect2
- CELA3A | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV99266753; called by muse, mutect2, varscan2
- CENPF | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as rs974261016, COSV65272395; called by muse, mutect2, varscan2
- CENPN | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as COSV55141661; called by muse, mutect2, varscan2
- CEP162 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 170/514 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs148340487; called by muse, mutect2, varscan2
- CEP250 | c.1220A>G p.Q407R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100699225; called by mutect2, varscan2
- CEP57 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100334842; called by muse, mutect2, varscan2
- CEP63 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100133143; called by muse, mutect2, varscan2
- CERT1 | c.1241_1243del p.R414del (on ENST00000405807 / NM_001130105.1; = p.R286del on NM_005713.3) | In Frame Del (DEL) | VAF 168/909 reads (18%) | catalogued as rs762582958; called by pindel, varscan2
- CFTR | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780526529, CM024682, CM983561, COSV50048079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHCHD5 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100260946; called by muse, mutect2, varscan2
- CHD5 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs527562697, COSV52424278; called by muse, mutect2
- CHD7 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101418482; called by muse, mutect2, varscan2
- CHD7 | c.4498A>G p.I1500V | Missense Mutation (SNP) | VAF 66/638 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV101418484; called by muse, varscan2
- CHI3L1 | c.468A>G p.E156= | Splice Region (SNP) | VAF 25/238 reads (11%) | catalogued as COSV99704179; called by muse, mutect2, varscan2
- CHRND | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs767665281, COSV51317389, COSV51318055; called by muse, mutect2, varscan2
- CHST9 | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52438373, COSV99411043; called by muse, mutect2, varscan2
- CLCC1 | c.947G>T p.G316V (on ENST00000356970 / NM_001377464.1; = p.G266V on NM_015127.5) | Missense Mutation (SNP) | VAF 126/556 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100206719; called by muse, mutect2, varscan2
- CLDN19 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99591776; called by muse, mutect2, varscan2
- CLEC12A | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100429708; called by muse, mutect2, varscan2
- CLIP1 | c.4127G>A p.R1376H (on ENST00000620786 / NM_001247997.1; = p.R1365H on NM_002956.2) | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367533743, COSV56810847; called by muse, mutect2, varscan2
- CLMN | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV54188695; called by muse, mutect2, varscan2
- CLMN | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774934404, COSV54184777; called by muse, mutect2, varscan2
- CLSTN1 | c.1466C>T p.P489L (on ENST00000377298 / NM_001009566.3; = p.P479L on NM_014944.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs375763180; called by muse, mutect2, varscan2
- CMYA5 | c.10778A>G p.E3593G | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101484405; called by muse, mutect2, varscan2
- CNTD1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 71/491 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.158); catalogued as COSV100162209; called by muse, mutect2, varscan2
- CNTNAP1 | c.2483G>A p.G828D | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.013); catalogued as COSV52849709, COSV99227085; called by muse, mutect2, varscan2
- COCH | c.965C>T p.T322M (on ENST00000216361 / NM_001347720.1; = p.T257M on NM_004086.3) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs963288777, COSV99363961; called by muse, mutect2, varscan2
- COG6 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100743417; called by muse, mutect2, varscan2
- COL12A1 | c.7126T>C p.F2376L | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486642; called by muse, mutect2
- COL17A1 | c.2621G>A p.G874D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100793384; called by muse, mutect2, varscan2
- COL5A1 | c.2955T>G p.G985= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100880617; called by muse, varscan2
- COL6A3 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs372255458; called by muse, mutect2, varscan2
- COL6A6 | c.4906G>T p.G1636* | Nonsense Mutation (SNP) | VAF 526/2037 reads (26%) | catalogued as COSV100651000; called by muse, mutect2, varscan2
- COLEC12 | c.2038C>A p.L680M | Missense Mutation (SNP) | VAF 124/413 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101232190; called by muse, mutect2, varscan2
- CPE | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 124/461 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV101291743; called by muse, varscan2
- CPEB4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.085); catalogued as COSV99437735; called by muse, mutect2, varscan2
- CRIM1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 330/1177 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs138252009; called by muse, mutect2, varscan2
- CRISPLD2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs1040279851, COSV52281503; called by muse, mutect2, varscan2
- CRNKL1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs577483196, COSV66106835; called by muse, mutect2
- CRYBG1 | c.5797A>G p.N1933D | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100954631; called by muse, mutect2, varscan2
- CRYZ | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100558730; called by muse, mutect2, varscan2
- CSDE1 | c.1955T>G p.V652G (on ENST00000358528 / NM_001007553.3; = p.V621G on NM_007158.6) | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99796102; called by muse, mutect2, varscan2
- CSE1L | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV53700890; called by muse, mutect2, varscan2
- CSGALNACT2 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.994); catalogued as COSV100989857; called by muse, mutect2, varscan2
- CSMD2 | c.7606G>A p.A2536T | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.595); catalogued as COSV99595963; called by muse, mutect2
- CSMD2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs1244988805, COSV53915073; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.7710T>A p.S2570R (on ENST00000297405 / NM_001363185.1; = p.S2466R on NM_052900.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99849124; called by muse, mutect2
- CSNK2A1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 159/695 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53937777, COSV99424750; called by muse, mutect2, varscan2
- CTSW | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100327576; called by muse, mutect2, varscan2
- CUL1 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | catalogued as COSV57387670; called by muse, mutect2, varscan2
- CXCR4 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1272938495, COSV54014780; called by muse, mutect2, varscan2
- CYFIP2 | c.3242T>C p.L1081P (on ENST00000616178 / NM_001291722.2; = p.L1056P on NM_014376.4) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100557845; called by muse, mutect2, varscan2
- CYP17A1 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100882149; called by muse, mutect2
- CYP1A2 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV100673944; called by muse, mutect2, varscan2
- CYP26B1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50015505, COSV99134366; called by muse, varscan2
- CYP2A13 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as COSV100387046; called by muse, mutect2, varscan2
- CYP2C19 | c.299T>G p.F100C | Missense Mutation (SNP) | VAF 127/533 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV100990638; called by muse, mutect2, varscan2
- CYP2R1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100585011; called by muse, mutect2
- CYP4B1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs139993247, COSV54723607; called by muse, mutect2, varscan2
- DBNL | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101289387; called by muse, mutect2, varscan2
- DCAF4 | c.271del p.L91* | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as COSV62320168; called by mutect2, pindel, varscan2
- DCAF4 | c.643T>G p.F215V | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV100611183; called by muse, mutect2, varscan2
- DCAF8L1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101491556; called by muse, varscan2
- DDB1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs754234630, COSV57105987; called by muse, mutect2, varscan2
- DDR1 | c.2452-1G>T p.X818_splice (on ENST00000324771; = p.X781_splice on NM_001954.4) | Splice Site (SNP) | VAF 17/347 reads (5%) | catalogued as COSV100242191; called by muse, mutect2
- DDR2 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100906985, COSV63374748; called by muse, mutect2
- DDX17 | c.1847G>A p.G616D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.303); catalogued as COSV99318389; called by muse, mutect2, varscan2
- DEF8 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as COSV99240790; called by muse, mutect2, varscan2
- DENND3 | c.3494C>A p.A1165E | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99371759; called by muse, mutect2, varscan2
- DHX15 | c.1786+2T>C p.X596_splice | Splice Site (SNP) | VAF 12/212 reads (6%) | catalogued as COSV100391799; called by muse, mutect2
- DHX16 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV100906107; called by muse, mutect2
- DHX32 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99502000; called by muse, mutect2
- DHX38 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99194611; called by muse, mutect2, varscan2
- DIP2A | c.3088G>A p.A1030T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV100596367; called by muse, mutect2, varscan2
- DISP1 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759714329, COSV52658475; called by muse, mutect2, varscan2
- DISP1 | c.4517C>A p.P1506H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99452289; called by muse, mutect2, varscan2
- DKK3 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs377759604; called by muse, mutect2, varscan2
- DLC1 | c.4535G>A p.R1512Q (on ENST00000276297 / NM_001348081.2; = p.R1075Q on NM_006094.5) | Missense Mutation (SNP) | VAF 220/817 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs747768907, COSV52328037; called by muse, mutect2, varscan2
- DLC1 | c.1993C>T p.R665C (on ENST00000276297 / NM_001348081.2; = p.R228C on NM_006094.5) | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1218116906, COSV99365773; called by muse, mutect2, varscan2
- DLC1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs148727515, COSV52324792; called by muse, mutect2, varscan2
- DMD | c.11022T>A p.N3674K | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.373); catalogued as COSV100629570; called by muse, mutect2, varscan2
- DMD | c.7495A>T p.M2499L | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100629573; called by muse, mutect2, varscan2
- DMD | c.3761T>C p.L1254P | Missense Mutation (SNP) | VAF 276/2378 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100823088; called by muse, mutect2, varscan2
- DNAH10 | c.8565G>T p.M2855I (on ENST00000409039; = p.M2794I on NM_207437.3) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV101292837, COSV69001369; called by muse, mutect2, varscan2
- DNAH11 | c.6836T>A p.V2279E | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181097; called by muse, mutect2
- DNAI2 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100210139; called by muse, mutect2, varscan2
- DNAJA1 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 16/186 reads (9%) | catalogued as rs751893930, COSV58310792; called by muse, mutect2
- DNAJC22 | c.958T>C p.F320L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs761677583, COSV101222613; called by muse, mutect2, varscan2
- DNAJC3 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100953270, COSV100953494; called by muse, mutect2, varscan2
- DNER | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs761933088, COSV59172750, COSV99080081; called by muse, varscan2
- DNER | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs777616075, COSV59164408; called by muse, mutect2, varscan2
- DNMT3B | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756972254, COSV52421823; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | catalogued as rs782552436; called by mutect2, pindel
- DOK5 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV99374913; called by muse, mutect2
- DPP8 | c.1577G>A p.G526E (on ENST00000341861 / NM_001320875.2; = p.G510E on NM_017743.6) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100202645; called by muse, mutect2, varscan2
- DPYSL4 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100634066; called by muse, mutect2, varscan2
- DROSHA | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 71/1092 reads (7%) | catalogued as COSV100757837; called by muse, mutect2
- DSEL | c.725T>C p.L242S | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100026147; called by muse, mutect2, varscan2
- DSG1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348931149, COSV57137662; called by muse, mutect2, varscan2
- DTWD2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs140154641; called by muse, mutect2, varscan2
- DYDC2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55471787; called by muse, mutect2, varscan2
- DYNC1I2 | c.734T>G p.F245C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV99784366; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 60/220 reads (27%) | catalogued as rs752987091; called by mutect2, varscan2
- EDAR | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764390189, COSV51501293; called by muse, mutect2, varscan2
- EDEM2 | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 75/419 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100993853; called by muse, mutect2, varscan2
- EFCAB14 | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 64/2334 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100905672; called by muse, mutect2
- EFCAB5 | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100300826; called by muse, mutect2
- EFHB | c.2089T>C p.Y697H | Missense Mutation (SNP) | VAF 138/1126 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55553992; called by muse, mutect2, varscan2
- EGR2 | c.485A>C p.D162A | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV99654323; called by muse, mutect2, varscan2
- EIF4G2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 133/979 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs780085043, COSV60597446; called by muse, mutect2, varscan2
- ELP4 | c.1217C>T p.A406V (on ENST00000350638; = p.A405V on NM_019040.5) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs906143735, COSV100635911; called by muse, mutect2, varscan2
- EMSY | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs774697937, COSV58259784; called by muse, mutect2, varscan2
- ENC1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV100188234; called by muse, varscan2
- ENTPD4 | c.1031A>T p.N344I | Missense Mutation (SNP) | VAF 268/1297 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as COSV100652809; called by mutect2, varscan2
- EPHA3 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559689115, COSV100349149; called by muse, mutect2, varscan2
- EPHA4 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs904777556, COSV56038112; called by muse, mutect2, varscan2
- EPS15 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as rs201144796, COSV100869613; called by muse, mutect2, varscan2
- ERCC1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 97/986 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV99185410; called by muse, mutect2, varscan2
- ERI2 | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99759522; called by muse, mutect2, varscan2
- ERICH3 | c.2959G>T p.V987F | Missense Mutation (SNP) | VAF 121/511 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs768455672, COSV100445930; called by muse, mutect2, varscan2
- ESF1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751200578, COSV99176406; called by muse, mutect2, varscan2
- ESR1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 291/1041 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99241445; called by muse, mutect2, varscan2
- ETNPPL | c.87T>A p.D29E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); catalogued as COSV99625714; called by muse, mutect2, varscan2
- EXOC2 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100034266; called by muse, varscan2
- EXOG | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV99815527; called by muse, mutect2, varscan2
- EXPH5 | c.3236A>T p.N1079I | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99762265; called by muse, mutect2, varscan2
- EXT1 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV100984142; called by muse, mutect2
- EXTL3 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 99/446 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs369382883, COSV55036628; called by muse, mutect2, varscan2
- F13B | c.1336T>C p.S446P | Missense Mutation (SNP) | VAF 257/997 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV100803479; called by muse, mutect2, varscan2
- FABP5 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.309); catalogued as COSV99793153; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM107B | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.035); catalogued as rs767708669, COSV99474493; called by muse, mutect2, varscan2
- FAM186B | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as COSV99220547; called by muse, mutect2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 22/155 reads (14%) | catalogued as COSV63726734; called by mutect2, pindel, varscan2
- FAM71E1 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.539); catalogued as rs1339233726, COSV58541448; called by muse, mutect2, varscan2
- FAM83A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 135/688 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754460595, COSV52686268; called by muse, varscan2
- FAM83C | c.1898G>A p.S633N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100981726; called by muse, mutect2, varscan2
- FANCM | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767799451, COSV99361205; called by muse, mutect2, varscan2
- FARP2 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs763386574, COSV50881344; called by muse, mutect2, varscan2
- FAT4 | c.7T>G p.L3V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV67886986; called by muse, mutect2, varscan2
- FBXL13 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as rs768134477, COSV99978704; called by muse, mutect2, varscan2
- FBXL13 | c.769A>C p.T257P | Missense Mutation (SNP) | VAF 115/481 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV99978705; called by muse, mutect2, varscan2
- FBXO10 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV99447325; called by muse, mutect2, varscan2
- FBXO31 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1053890244, COSV100291629; called by muse, mutect2, varscan2
- FCHSD1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1035904239, COSV99500342; called by muse, mutect2, varscan2
- FGD5 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs199737604; called by muse, varscan2
- FGF14 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 166/1766 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs199536239, COSV65935211; called by muse, mutect2
- FGF23 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99426737; called by muse, mutect2
- FGF9 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV101211033; called by muse, mutect2
- FGG | c.1289del p.G430Efs*33 (on ENST00000336098 / NM_021870.3; = p.G430Efs*24 on NM_000509.5) | Frame Shift Del (DEL) | VAF 172/1158 reads (15%) | catalogued as rs1560833290, COSV60195824; called by mutect2, pindel, varscan2
- FLNC | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs775085661, COSV57958345, COSV57966882; called by muse, mutect2
- FLT1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs755339233, COSV56725445; called by muse, mutect2, varscan2
- FOXD4 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58700483; called by muse, mutect2, varscan2
- FOXK2 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV100082477; called by muse, mutect2
- FOXP1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs935869094, COSV59516900; called by muse, mutect2, varscan2
- FPGT | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100907586; called by muse, mutect2, varscan2
- FREM2 | c.3964A>G p.I1322V | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99751201; called by muse, mutect2
- FRMPD2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs111596155, COSV59716312; called by muse, mutect2, varscan2
- FYCO1 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs748731437, COSV99946321; called by muse, varscan2
- GABRR3 | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101512361; called by muse, mutect2, varscan2
- GASK1B | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.314); catalogued as COSV56710844; called by muse, mutect2, varscan2
- GBX2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103628; called by muse, mutect2, varscan2
- GCKR | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs761397252, COSV53106414; called by muse, mutect2
- GCSAM | c.151del p.I51Yfs*138 | Frame Shift Del (DEL) | VAF 94/397 reads (24%) | catalogued as rs762814436; called by mutect2, pindel, varscan2
- GGH | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs1205167771; called by muse, mutect2, varscan2
- GIGYF2 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs749146143, COSV65253717; called by muse, mutect2, varscan2
- GLYR1 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100424580; called by muse, mutect2, varscan2
- GML | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV99638644; called by muse, mutect2, varscan2
- GNA11 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV50018791; called by muse, mutect2, varscan2
- GNAZ | c.808A>G p.N270D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99321262; called by muse, mutect2, varscan2
- GPD2 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 10/232 reads (4%) | catalogued as rs1010988379; called by muse, mutect2
- GPR139 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 32/511 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032845174, COSV58503205; called by muse, mutect2
- GPR142 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV59518929, COSV59520310; called by muse, mutect2, varscan2
- GRB14 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs775435444, COSV55737049, COSV99813928; called by muse, varscan2
- GRIK5 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs776996571, COSV99491423; called by muse, mutect2
- GRIP1 | c.1345A>C p.K449Q (on ENST00000359742 / NM_001379345.1; = p.K397Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 334/1021 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV99671170; called by muse, mutect2, varscan2
- GRIPAP1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 130/589 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV64552507; called by muse, mutect2, varscan2
- GRM1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs553512718, COSV51109088; called by muse, mutect2, varscan2
- GRM6 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs751541548, COSV51444853; called by muse, mutect2, varscan2
- GSE1 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs368544307; called by muse, mutect2, varscan2
- GSN | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100376618; called by muse, mutect2
- GTF3C1 | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772993464, COSV62238813; called by muse, mutect2, varscan2
- GUF1 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV99777052; called by muse, varscan2
- H2BC18 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.147); catalogued as COSV100516193; called by muse, mutect2, varscan2
- HDX | c.1192del p.S398Lfs*10 | Frame Shift Del (DEL) | VAF 154/638 reads (24%) | catalogued as COSV99946980; called by mutect2, pindel, varscan2
- HEATR5A | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as COSV101120618; called by muse, mutect2, varscan2
- HERC2 | c.14420C>A p.A4807D | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1300325322, COSV55345244; called by muse, mutect2
- HFM1 | c.4163del p.N1388Tfs*37 | Frame Shift Del (DEL) | VAF 61/232 reads (26%) | catalogued as rs759278255; called by mutect2, varscan2
- HHIPL2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762521443, COSV58567164; called by muse, mutect2, varscan2
- HIRA | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99600942; called by muse, mutect2
- HLA-DMB | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs1164573532, COSV101186855; called by muse, varscan2
- HLX | c.1222A>C p.K408Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as rs554006386, COSV100854640; called by muse, varscan2
- HMCN1 | c.14000C>A p.A4667E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV99636475; called by muse, mutect2, varscan2
- HMCN1 | c.16414G>T p.D5472Y | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99636478; called by muse, mutect2, varscan2
- HNRNPA3 | c.195+1G>C p.X65_splice | Splice Site (SNP) | VAF 34/142 reads (24%) | catalogued as COSV101182974; called by muse, mutect2, varscan2
- HNRNPLL | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99696741; called by muse, mutect2
- HOOK1 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs774010985, COSV100969269; called by muse, varscan2
- HOXA11 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419108203, COSV99136131; called by muse, mutect2, varscan2
- HOXC12 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99678826; called by muse, mutect2, varscan2
- HPD | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100000244; called by muse, mutect2, varscan2
- HRC | c.1212G>T p.E404D | Missense Mutation (SNP) | VAF 291/1070 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV99418380; called by muse, mutect2, varscan2
- HSD3B7 | c.543del p.L182Cfs*4 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV52682172; called by mutect2, pindel
- HSP90AB1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 36/465 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs370988754, COSV62335960; called by muse, mutect2
- HSP90B1 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 123/476 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368374645; called by muse, varscan2
- HTR1F | c.485G>T p.R162M | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100138334; called by muse, mutect2
- HTRA2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV99239975; called by muse, mutect2, varscan2
- HUWE1 | c.4510A>C p.T1504P | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99474432; called by muse, mutect2, varscan2
- ICA1 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 181/640 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV99655412; called by muse, mutect2, varscan2
- IDH1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs555882127, COSV61620782; called by muse, mutect2
- IFI44 | c.566T>A p.I189N | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100877438; called by muse, mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IGF2R | c.6160G>A p.V2054I | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1449697283, COSV63630668; called by muse, mutect2
- IGHMBP2 | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1325161979, COSV99662631; called by muse, mutect2, varscan2
- IGLON5 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs527614882, COSV54536135; called by muse, mutect2, varscan2
- IGSF1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1215064968, COSV63836099; called by muse, mutect2, varscan2
- IHO1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV99606628; called by muse, mutect2, varscan2
- IL12RB1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.254); catalogued as COSV100443223; called by muse, varscan2
- IL16 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57268413; called by muse, mutect2, varscan2
- ING1 | c.1132T>C p.W378R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312399; called by muse, mutect2, varscan2
- INHBA | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54219953; called by muse, varscan2
- INSIG2 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 106/1055 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV99830490, COSV99830510; called by muse, mutect2, varscan2
- INSL6 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 209/1061 reads (20%) | catalogued as COSV101068543; called by muse, mutect2, varscan2
- INTU | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100081436; called by muse, mutect2
- IQUB | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.367); catalogued as COSV100227391; called by muse, mutect2, varscan2
- IRX5 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.151); catalogued as rs1361620381, COSV100316026; called by muse, mutect2, varscan2
- ISLR2 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as rs1322030287, COSV100679805; called by muse, mutect2
- ITGB8 | c.2065A>G p.I689V | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.952); catalogued as rs1462768505, COSV99752492; called by muse, mutect2
- ITIH1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs763101480, COSV99835290; called by muse, mutect2, varscan2
- ITIH3 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779110584, COSV56578644; called by muse, mutect2
- ITPR1 | c.2818G>T p.G940* (on ENST00000354582; = p.G925* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 24/350 reads (7%) | catalogued as COSV100233347; called by muse, mutect2
- ITPRIPL1 | c.730C>A p.P244T (on ENST00000439118 / NM_001008949.3; = p.P252T on NM_178495.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100742250, COSV63152649; called by muse, mutect2, varscan2
- IVNS1ABP | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 154/552 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as rs148769727; called by muse, varscan2
- JADE1 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV99886352; called by muse, mutect2
- JAKMIP1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 254/740 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs756138238, COSV99290889; called by muse, varscan2
- JMJD1C | c.3253C>A p.P1085T | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100550877; called by muse, mutect2, varscan2
- JRK | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.598); catalogued as rs781988769; called by muse, varscan2
- KANSL1 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99294991; called by muse, mutect2, varscan2
- KAT6A | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 286/1116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99705965; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 78/294 reads (27%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KCNA4 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100069304; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 16/180 reads (9%) | catalogued as rs1258313537; called by mutect2, pindel
- KCNA4 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs747595084, COSV60251264; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNH1 | c.2212C>T p.R738W (on ENST00000271751 / NM_172362.3; = p.R711W on NM_002238.4) | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs908699888, COSV55082228; called by muse, mutect2, varscan2
- KCNJ10 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.754); catalogued as rs758441824, COSV63632862; called by muse, mutect2
- KCTD13 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100441866; called by muse, mutect2, varscan2
- KDM2B | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs368219190, COSV100997292; called by muse, mutect2
- KDM5B | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1236674068, COSV52511996; called by muse, mutect2, varscan2
- KDR | c.2030C>T p.T677M | Missense Mutation (SNP) | VAF 109/532 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs200338299, COSV55757334, COSV99817009; called by muse, mutect2, varscan2
- KHSRP | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101231253; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 50/210 reads (24%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIAA1109 | c.9883T>A p.W3295R | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99178777; called by muse, mutect2, varscan2
- KIAA1109 | c.13588G>A p.V4530I | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV99178787; called by muse, mutect2
- KIAA1217 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.674); catalogued as rs758030089, COSV64604852; called by muse, mutect2, varscan2
- KIF13B | c.3863del p.K1288Rfs*13 | Frame Shift Del (DEL) | VAF 64/228 reads (28%) | catalogued as rs1287634008; called by mutect2, pindel, varscan2
- KIF17 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs574381737, COSV99929866; called by muse, mutect2, varscan2
- KIF24 | c.3536C>T p.T1179M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs781559463, COSV52658222; called by muse, mutect2, varscan2
- KIF26B | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771122784, COSV63636258; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF12 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV100888702; called by muse, mutect2, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs762518653; called by pindel, varscan2*
- KLHL42 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 160/506 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV101179871; called by muse, mutect2, varscan2
- KLHL6 | c.282C>A p.S94R | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100385079; called by muse, mutect2, varscan2
- KLRG1 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99868654; called by muse, mutect2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 159/646 reads (25%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KRIT1 | c.611A>C p.N204T | Missense Mutation (SNP) | VAF 67/808 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100388960; called by muse, mutect2
- L34079.1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 134/376 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs757597704, COSV60671027; called by muse, mutect2, varscan2
- LAMA2 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV101370877; called by muse, mutect2, varscan2
- LAMB4 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99225786; called by muse, mutect2, varscan2
- LARP4B | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as rs148067710; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 170/850 reads (20%) | catalogued as COSV60222740; called by mutect2, varscan2
- LASP1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1450523315, COSV58803906; called by muse, mutect2, varscan2
- LDB2 | c.706T>C p.F236L | Missense Mutation (SNP) | VAF 60/786 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100455000; called by muse, mutect2
- LDLRAD3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs752803367, COSV59683277; called by muse, mutect2, varscan2
- LENG1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs377766733, COSV55366816; called by muse, mutect2, varscan2
- LHX5 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55662779; called by muse, varscan2
- LILRB1 | c.841C>A p.Q281K (on ENST00000427581; = p.Q245K on NM_006669.6) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61122221; called by muse, mutect2, varscan2
- LIMCH1 | c.1452T>A p.N484K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV100574562; called by muse, mutect2, varscan2
- LIMCH1 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100574566; called by muse, mutect2
- LMAN2 | c.433+1G>A p.X145_splice | Splice Site (SNP) | VAF 63/265 reads (24%) | catalogued as COSV100288517; called by muse, mutect2, varscan2
- LMBRD2 | c.1070C>A p.S357* | Nonsense Mutation (SNP) | VAF 40/340 reads (12%) | catalogued as COSV99683286; called by muse, mutect2, varscan2
- LMCD1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs752204449, COSV99337277; called by muse, mutect2, varscan2
- LNX1 | c.1576G>A p.A526T (on ENST00000263925 / NM_001126328.3; = p.A430T on NM_032622.2) | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs1415282636, COSV99820670; called by muse, mutect2, varscan2
- LNX2 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs199501730, COSV60336011; called by muse, mutect2, varscan2
- LONP1 | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs138631909; called by muse, mutect2, varscan2
- LRP2BP | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 147/578 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295195450, COSV100145954; called by muse, mutect2, varscan2
- LRP6 | c.4522A>C p.S1508R | Missense Mutation (SNP) | VAF 130/2400 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.877); catalogued as COSV99744640; called by muse, mutect2
- LRRC1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100906600; called by muse, mutect2, varscan2
- LRRC30 | c.752T>A p.L251H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775926318, COSV101274461; called by muse, mutect2, varscan2
- LRRC4B | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV100976059; called by muse, mutect2, varscan2
- LRRC52 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs769884053, COSV54233994; called by muse, mutect2, varscan2
- LTN1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.382); catalogued as rs1240429756, COSV100798252; called by muse, mutect2, varscan2
- LYPD3 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99747259; called by muse, mutect2, varscan2
- M1AP | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99303598; called by muse, mutect2
- MACF1 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs766885627, COSV100486672; called by muse, mutect2
- MACF1 | c.10094G>T p.R3365L | Missense Mutation (SNP) | VAF 129/518 reads (25%) | catalogued as COSV99247144; called by muse, mutect2, varscan2
- MAD1L1 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs757932885, COSV99767738; called by muse, mutect2, varscan2
- MADD | c.2974G>A p.D992N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.2); catalogued as rs748863441, COSV60623499; called by muse, mutect2, varscan2
- MADD | c.4208C>T p.S1403L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs759842048, COSV100212037; called by muse, mutect2
- MAGEB1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100975122; called by muse, mutect2, varscan2
- MAGEL2 | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100046254; called by muse, mutect2, varscan2
- MAML2 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 60/573 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV101594203; called by muse, mutect2
- MAN1B1 | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100858164; called by muse, mutect2, varscan2
- MAP2 | c.4007C>A p.A1336E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.129); catalogued as COSV99561863; called by muse, varscan2
- MAP2 | c.4071A>T p.E1357D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99561867; called by muse, varscan2
- MAP2K2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV53563098; called by mutect2, varscan2
- MAP3K11 | c.2037del p.T680Rfs*267 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs1554987893, COSV58421031; called by mutect2, varscan2
- MAP3K13 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs202042288, COSV99406772; called by muse, mutect2, varscan2
- MAP4 | c.851T>C p.L284S | Missense Mutation (SNP) | VAF 115/717 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100806402; called by muse, mutect2, varscan2
- MAP4K4 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 150/583 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100155989; called by muse, mutect2, varscan2
- MAP7 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100644043; called by muse, mutect2, varscan2
- MAST2 | c.2137A>C p.I713L | Missense Mutation (SNP) | VAF 163/539 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV100788830; called by muse, mutect2, varscan2
- MCOLN3 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353057; called by muse, mutect2, varscan2
- ME1 | c.19del p.R7Vfs*12 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | catalogued as rs770202820; called by mutect2, pindel, varscan2
- MED12 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV100380155; called by muse, mutect2
- MED12L | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.858); catalogued as rs752139829, COSV56369418; called by muse, mutect2, varscan2
- MEI1 | c.2869T>C p.S957P | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100300398; called by muse, mutect2, varscan2
- MEIS3 | c.950G>A p.R317Q (on ENST00000558555 / NM_001346148.1; = p.R363Q on NM_020160.3) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100520566; called by muse, mutect2, varscan2
- MELTF | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99586649; called by muse, mutect2, varscan2
- METTL6 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV101085111; called by muse, mutect2, varscan2
- MFSD13A | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV53266868; called by muse, varscan2
- MFSD6 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99855451; called by muse, mutect2, varscan2
- MGAT1 | c.1130A>G p.D377G | Missense Mutation (SNP) | VAF 11/89 reads (12%) | PolyPhen benign (0.024); catalogued as rs1430731097, COSV100286851; called by muse, mutect2, varscan2
- MICAL2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 53/563 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1046278859, COSV56316924; called by muse, mutect2
- MICU1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs752729268, COSV100741954; called by muse, mutect2, varscan2
- MINAR1 | c.2174G>A p.S725N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as rs772546855, COSV100549338; called by mutect2, varscan2
- MKI67 | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 237/1032 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs770946589, COSV64076468; called by muse, mutect2, varscan2
- MPP3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV101263367; called by muse, mutect2, varscan2
- MRGPRX4 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV58590446; called by muse, mutect2
- MRPL53 | c.61T>A p.C21S | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV99252271; called by muse, mutect2, varscan2
- MSH6 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as rs63750440, COSV52277030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTERF4 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99613007; called by muse, mutect2
- MTOR | c.4847G>A p.R1616H | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1297595805, COSV63867987; called by muse, mutect2, varscan2
- MUC16 | c.40175A>G p.D13392G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); catalogued as COSV101110104; called by muse, mutect2
- MUC16 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 294/1132 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV101201863; called by muse, mutect2, varscan2
- MUC20 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528684754, COSV100290845; called by mutect2, varscan2
- MYBL1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 212/673 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs61753806; called by muse, varscan2
- MYH10 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as rs1173588107, COSV99346474; called by muse, mutect2
- MYH14 | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373919106, COSV51824636; called by mutect2, varscan2
- MYLK | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs750362610, COSV100659712; called by muse, varscan2
- MYO19 | c.2353C>T p.R785W (on ENST00000614623 / NM_001163735.1; = p.R585W on NM_025109.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1046180887; called by muse, varscan2
- NAP1L2 | c.1226C>A p.S409* | Nonsense Mutation (SNP) | VAF 89/356 reads (25%) | catalogued as COSV100999235; called by muse, mutect2, varscan2
- NAP1L3 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100220712; called by muse, mutect2, varscan2
- NBEA | c.8533C>T p.R2845* | Nonsense Mutation (SNP) | VAF 56/225 reads (25%) | catalogued as rs1288199769, COSV59762270; called by muse, mutect2, varscan2
- NBEAL1 | c.5848_5850del p.R1950del | In Frame Del (DEL) | VAF 32/166 reads (19%) | catalogued as rs1358111334; called by pindel, varscan2
- NBN | c.1911A>G p.I637M | Missense Mutation (SNP) | VAF 120/590 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as rs372877871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCBP1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100912695; called by muse, mutect2
- NCKIPSD | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 131/500 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs762789060, COSV53660723; called by muse, mutect2, varscan2
- NDUFS3 | c.263T>A p.I88N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99772521; called by muse, mutect2, varscan2
- NEB | c.19701C>A p.S6567R | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99428403; called by muse, mutect2, varscan2
- NEB | c.14780C>T p.A4927V | Missense Mutation (SNP) | VAF 121/459 reads (26%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.995); catalogued as rs937323081, COSV99428405; called by muse, mutect2, varscan2
- NEB | c.4252G>A p.A1418T | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.527); catalogued as rs1444597977, COSV51466070; called by muse, mutect2, varscan2
- NEDD9 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs1226283753, COSV65221469; called by muse, mutect2, varscan2
- NES | c.4521G>T p.L1507F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV63961042; called by muse, mutect2, varscan2
- NETO1 | c.1566C>A p.S522R | Missense Mutation (SNP) | VAF 387/1646 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs756961581, COSV100199832; called by muse, mutect2, varscan2
- NFASC | c.1474C>T p.R492C (on ENST00000339876 / NM_001378329.1; = p.R503C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs531423904, COSV100362363, COSV58358373; called by muse, mutect2, varscan2
- NFATC4 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs778408359, COSV51596112; called by muse, mutect2, varscan2
- NFE2 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1183797955, COSV100380860; called by muse, mutect2, varscan2
- NFKBID | c.506G>A p.R169H (on ENST00000396901; = p.R321H on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs768512398, COSV100756539; called by muse, mutect2, varscan2
- NIM1K | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.109); catalogued as COSV100390523, COSV58143632; called by muse, mutect2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 49/185 reads (26%) | catalogued as rs145147241; called by mutect2, varscan2
- NKAPL | c.565del p.R189Efs*89 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs768650749, COSV59199043; called by mutect2, pindel, varscan2
- NLGN1 | c.822T>G p.H274Q | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); catalogued as COSV100850274; called by muse, mutect2, varscan2
- NLGN4X | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.965); catalogued as rs776615616, COSV52030210; called by muse, mutect2, varscan2
- NOMO1 | c.3057G>T p.K1019N | Missense Mutation (SNP) | VAF 53/554 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV99814917; called by muse, mutect2, varscan2
- NPAP1 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.813); catalogued as COSV100276271; called by muse, mutect2
- NPBWR1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs567536404, COSV100488325; called by muse, mutect2, varscan2
- NPEPPS | c.2244T>A p.Y748* | Nonsense Mutation (SNP) | VAF 165/841 reads (20%) | catalogued as COSV100444017; called by muse, varscan2
- NPLOC4 | c.70_71del p.E24Nfs*18 | Frame Shift Del (DEL) | VAF 53/499 reads (11%) | catalogued as rs746078041; called by pindel, varscan2
- NPR2 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100709764; called by muse, mutect2
- NRDC | c.1718G>T p.S573I | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100703925; called by muse, mutect2
- NRIP1 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 31/602 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV100013152; called by muse, mutect2
- NRK | c.1009del p.R337Dfs*8 | Frame Shift Del (DEL) | VAF 48/192 reads (25%) | catalogued as rs1336364406; called by pindel, varscan2
- NRXN3 | c.301C>T p.P101S (on ENST00000557594 / NM_001272020.2; = p.P733S on NM_004796.6) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99822201; called by muse, mutect2, varscan2
- NT5C3B | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV53172651; called by muse, mutect2
- NTM | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.232); catalogued as COSV100869614; called by muse, mutect2, varscan2
- NUAK1 | c.1944G>T p.Q648H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99777357; called by muse, mutect2
- NUP85 | c.1379G>T p.R460L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV99822374; called by muse, mutect2, varscan2
- NUP98 | c.4973C>T p.A1658V (on ENST00000359171 / NM_001365126.1; = p.A1641V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as COSV100263538; called by muse, mutect2
- OBSCN | c.14480G>A p.G4827D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99484776; called by muse, mutect2, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 132/395 reads (33%) | catalogued as rs777887578; called by mutect2, varscan2
- OGDHL | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100934549; called by muse, mutect2, varscan2
- OLFM3 | c.184G>A p.D62N (on ENST00000338858 / NM_001288821.1; = p.D42N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV58796769, COSV58802891; called by muse, mutect2
- OLFML2A | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs372603527, COSV56585745; called by mutect2, varscan2
- OPCML | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770223558, COSV59410726; called by muse, mutect2, varscan2
- OR11L1 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100869498; called by muse, mutect2, varscan2
- OR2M3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs138010167; called by muse, varscan2
- OR2T11 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100424984; called by muse, mutect2, varscan2
- OR2Z1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs373819151; called by muse, mutect2, varscan2
- OR4D6 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55660749; called by muse, mutect2, varscan2
- OR51A7 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs754702889, COSV100834769; called by muse, mutect2, varscan2
- OR56A4 | c.257T>A p.L86H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100417715; called by muse, mutect2, varscan2
- OR5M3 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392520, COSV56565606; called by muse, mutect2
- OR5R1 | c.388_389insA p.L130Hfs*46 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | catalogued as COSV100393607; called by mutect2, pindel, varscan2
- OR6M1 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100484195; called by muse, mutect2
- OR6N1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs750835558, COSV100625305; called by muse, mutect2, varscan2
- OSBP2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773995691, COSV100213857; called by mutect2, varscan2
- OSBPL7 | c.369G>A p.K123= | Splice Region (SNP) | VAF 64/235 reads (27%) | catalogued as COSV99137094; called by muse, mutect2, varscan2
- OTOF | c.5244C>G p.D1748E (on ENST00000272371 / NM_194248.3; = p.D981E on NM_004802.4) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs780139913, COSV55499307, COSV55520806; called by muse, mutect2, varscan2
- PAN3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 40/289 reads (14%) | catalogued as COSV56700966; called by muse, mutect2, varscan2
- PANK4 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347419308, COSV65867708; called by muse, mutect2, varscan2
- PAPPA | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775541104, COSV60290312; called by muse, mutect2, varscan2
- PARD3 | c.1492dup p.A498Gfs*9 | Frame Shift Ins (INS) | VAF 20/184 reads (11%) | catalogued as rs781028175; called by mutect2, pindel, varscan2
- PARP1 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs190105316, CM150689, COSV100829068; called by muse, mutect2, varscan2
- PARP8 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 169/778 reads (22%) | catalogued as COSV99890497; called by muse, mutect2, varscan2
- PASK | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs773268908, COSV52152780; called by muse, mutect2, varscan2
- PBX4 | c.1054del p.A352Pfs*28 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1368762457, COSV52062778; called by mutect2, pindel
- PCARE | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs767286082, COSV59054672; called by muse, mutect2, varscan2
- PCARE | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100527915, COSV59052898; called by muse, mutect2, varscan2
- PCDH10 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV99994610; called by muse, mutect2, varscan2
- PCDH15 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751941551, CM165391, COSV57288231, COSV57352576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH18 | c.2678T>C p.I893T | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs771968738, COSV100787536; called by muse, mutect2, varscan2
- PCDH8 | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100131053, COSV100132077; called by muse, mutect2, varscan2
- PCDHB1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1384862222, COSV100128433; called by muse, mutect2, varscan2
- PCDHB11 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs782466228, COSV53381684; called by muse, mutect2, varscan2
- PCDHB7 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs782586618, COSV50769229; called by muse, mutect2, varscan2
- PCDHGA12 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52772964; called by muse, mutect2, varscan2
- PCDHGA7 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs774353364, COSV54029028; called by muse, mutect2, varscan2
- PCLO | c.11569A>G p.R3857G | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV61616419, COSV61672717; called by muse, mutect2, varscan2
- PCNX1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1019783360, COSV99457406; called by muse, mutect2, varscan2
- PCNX1 | c.4834C>T p.R1612W | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53098102; called by muse, mutect2
- PCSK5 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100950750; called by muse, mutect2
- PDE3B | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 52/528 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868203610, COSV56384085, COSV99963364; called by muse, mutect2
- PDE3B | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 163/656 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146384818; called by muse, mutect2, varscan2
- PDE9A | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 132/592 reads (22%) | catalogued as COSV52330830, COSV99372284; called by muse, mutect2, varscan2
- PDGFRA | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs1308521786, COSV57268909, COSV57269165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDIA5 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs772836826, COSV100299605; called by muse, mutect2, varscan2
- PDZD7 | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 81/382 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV100931718; called by muse, mutect2, varscan2
- PDZRN4 | c.2765G>A p.R922Q (on ENST00000402685 / NM_001164595.2; = p.R664Q on NM_013377.4) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207064397, COSV100114802, COSV54221611; called by muse, mutect2, varscan2
- PELO | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99252255; called by muse, mutect2, varscan2
- PER3 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375445968, COSV100728504; called by muse, mutect2, varscan2
- PEX14 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV100750326; called by muse, mutect2
- PGBD2 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV61401153; called by muse, mutect2, varscan2
- PGLYRP1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs555905155, COSV50517656; called by muse, mutect2, varscan2
- PHAX | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99881700; called by muse, mutect2, varscan2
- PHF14 | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 275/988 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101301866; called by muse, mutect2, varscan2
- PHF21A | c.890C>T p.T297M (on ENST00000418153 / NM_001101802.3; = p.T298M on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/816 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV99139480; called by muse, mutect2, varscan2
- PHF3 | c.3376G>A p.A1126T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100014060; called by muse, mutect2
- PHKA2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 70/792 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs191267737, COSV66055277; called by muse, mutect2
- PHKA2 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101177509; called by muse, mutect2, varscan2
- PHLDB2 | c.2490C>T p.G830= (on ENST00000393925 / NM_001134439.2; = p.G787= on NM_145753.2) | Splice Region (SNP) | VAF 63/604 reads (10%) | catalogued as COSV101208733; called by muse, mutect2, varscan2
- PHLPP1 | c.3505G>A p.G1169R | Missense Mutation (SNP) | VAF 434/1630 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs901673793, COSV53031373; called by muse, mutect2, varscan2
- PHTF2 | c.1123G>A p.A375T (on ENST00000248550 / NM_001366089.1; = p.A337T on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs368376693; called by muse, mutect2
- PI4KA | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV55423760; called by muse, varscan2
- PICK1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV57635701; called by muse, mutect2, varscan2
- PIK3C2B | c.3133C>A p.L1045M | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV100916233; called by muse, mutect2
- PIK3R5 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs765654812, COSV52651342; called by muse, mutect2
- PIP4K2A | c.1140C>T p.G380= | Splice Region (SNP) | VAF 44/384 reads (11%) | catalogued as rs549534439, COSV60541739; called by muse, varscan2
- PKHD1L1 | c.3073A>G p.R1025G | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV65750603; called by muse, mutect2, varscan2
- PKN2 | c.2563-1G>C p.X855_splice | Splice Site (SNP) | VAF 172/593 reads (29%) | catalogued as COSV100981438; called by muse, mutect2, varscan2
- PLAGL1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 119/576 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs753924230, COSV99394317; called by muse, mutect2, varscan2
- PLB1 | c.1923A>G p.E641= | Splice Region (SNP) | VAF 44/204 reads (22%) | catalogued as COSV100215510; called by muse, mutect2, varscan2
- PLBD2 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761114976, COSV99785538; called by muse, mutect2, varscan2
- PLCB2 | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1402719071, COSV53030922; called by muse, mutect2, varscan2
- PLCD1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377962337, COSV100587764; called by muse, mutect2, varscan2
- PLEKHG1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 22/702 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1020557283, COSV100651911; called by muse, mutect2
- PLIN4 | c.1460C>T p.A487V (on ENST00000301286; = p.A502V on NM_001367868.2) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100014241; called by muse, mutect2, varscan2
- PLXNC1 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.169); catalogued as rs756645590, COSV99312530, COSV99313932; called by muse, mutect2, varscan2
- PNPLA4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV101124436; called by muse, mutect2, varscan2
- POLD1 | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV101486935; called by muse, mutect2, varscan2
- POLDIP3 | c.909T>G p.C303W | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459745170, COSV52808624; called by muse, mutect2, varscan2
- POLR1A | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as rs375330613; called by muse, mutect2, varscan2
- PORCN | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.445); catalogued as COSV100400573; called by muse, mutect2, varscan2
- POSTN | c.1744A>G p.T582A | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101123511; called by muse, mutect2
- POU4F2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs747030570, COSV55582913; called by mutect2, varscan2
- PPARD | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.379); catalogued as rs752963884, COSV100283372; called by muse, mutect2, varscan2
- PPCS | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65333968; called by muse, mutect2, varscan2
- PPIG | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 80/549 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); catalogued as COSV53641765; called by muse, mutect2, varscan2
- PPP1R13L | c.1683dup p.P562Afs*10 | Frame Shift Ins (INS) | VAF 19/43 reads (44%) | catalogued as rs780494005; called by mutect2, pindel, varscan2
- PPP1R3F | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50019331; called by muse, mutect2, varscan2
- PRAG1 | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779727371, COSV100422907; called by mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | catalogued as rs537061158; called by mutect2, varscan2
- PROP1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); catalogued as rs748484817, COSV57644868; called by muse, varscan2
- PRORP | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.022); catalogued as COSV99156598; called by muse, mutect2
- PRPF38B | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs750555207, COSV100898346; called by muse, mutect2, varscan2
- PRPF8 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1448269550, COSV100517982, COSV59266736; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.958G>A p.V320M (on ENST00000352766; = p.V241M on NM_181334.5) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs562703546, COSV100424711; called by muse, mutect2, varscan2
- PRRC2C | c.1549C>T p.R517C (on ENST00000367742; = p.R515C on NM_015172.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs374981644; called by muse, mutect2, varscan2
- PRRC2C | c.2395G>A p.A799T (on ENST00000367742; = p.A797T on NM_015172.4) | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1223429583, COSV100145337; called by muse, mutect2
- PRRC2C | c.7417C>T p.P2473S (on ENST00000367742; = p.P2471S on NM_015172.4) | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.162); catalogued as COSV100146152; called by muse, mutect2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSMB2 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100951613, COSV64699148; called by muse, mutect2, varscan2
- PSMB6 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1294459124, COSV99567013; called by muse, mutect2, varscan2
- PSMD10 | c.352A>G p.R118G | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV99480752; called by muse, mutect2, varscan2
- PSPH | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV51913037; called by muse, mutect2, varscan2
- PTDSS1 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100428982; called by muse, mutect2, varscan2
- PTGER4 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100201786; called by muse, mutect2, varscan2
- PTGS1 | c.381del p.T128Pfs*17 | Frame Shift Del (DEL) | VAF 37/351 reads (11%) | catalogued as rs779702921; called by mutect2, pindel, varscan2
- PTH1R | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs768504854, COSV100481190; called by mutect2, varscan2
- PTH2R | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 201/673 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553009188, COSV99782945; called by muse, mutect2, varscan2
- PTPN6 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59684595; called by muse, mutect2, varscan2
- PTPRB | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 145/562 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.437); catalogued as COSV99719132; called by muse, mutect2, varscan2
- RAB17 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs775097225, COSV52816095; called by mutect2, varscan2
- RAB9B | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99686148; called by muse, mutect2, varscan2
- RALGAPB | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1396752267, COSV99485889; called by muse, mutect2, varscan2
- RASSF2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs754308859, COSV65082426; called by mutect2, varscan2
- RASSF4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1264885834, COSV58489026; called by muse, mutect2, varscan2
- RBL2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 93/330 reads (28%) | catalogued as COSV50873483; called by muse, varscan2
- RBM12 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100468192; called by muse, mutect2, varscan2
- RBM15 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs113985065, COSV100873518, COSV63923486; called by muse, mutect2, varscan2
- RELCH | c.3452A>G p.E1151G | Missense Mutation (SNP) | VAF 26/718 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99902846; called by muse, mutect2
- RELN | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 66/597 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs752141793, COSV100633755, COSV100634990; called by muse, varscan2
- REXO4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs988432346, COSV100905781; called by muse, mutect2
- RFC1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 162/544 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1441302773, COSV100568074; called by muse, mutect2, varscan2
- RFX3 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 43/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56510138; called by muse, mutect2, varscan2
- RFX4 | c.916C>T p.R306* (on ENST00000392842 / NM_213594.3; = p.R212* on NM_032491.6) | Nonsense Mutation (SNP) | VAF 111/341 reads (33%) | catalogued as COSV57575496; called by muse, mutect2, varscan2
- RFX6 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 295/962 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100264355; called by muse, mutect2, varscan2
- RHPN2 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs753950362, COSV54279253; called by muse, mutect2, varscan2
- RIMS2 | c.2881C>T p.R961W (on ENST00000666250 / NM_001348490.2; = p.R769W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1348777772, COSV99200875; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RIOK1 | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV99344939; called by mutect2, varscan2
- RMND5B | c.283_284del p.R95Efs*5 | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | catalogued as rs776244882; called by mutect2, pindel, varscan2
- RNF25 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs755319283, COSV99829242; called by mutect2, varscan2
- RNF31 | c.3205del p.R1069Afs*6 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | catalogued as COSV60703154; called by mutect2, pindel, varscan2
- RNF8 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100009914; called by muse, mutect2
- RP1L1 | c.2864C>A p.A955D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101223678; called by muse, mutect2, varscan2
- RPF1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394394121, COSV101039840; called by muse, mutect2, varscan2
- RPGRIP1 | c.2645C>A p.P882H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV52847653; called by muse, mutect2, varscan2
- RPGRIP1L | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 64/592 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV100046883; called by muse, mutect2, varscan2
- RPH3A | c.2041C>T p.R681C (on ENST00000389385 / NM_001143854.2; = p.R677C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372862366; called by muse, mutect2
- RPL18A | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs761003483, COSV99714523; called by muse, mutect2, varscan2
- RPS6KB1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.388); catalogued as rs1410557496, COSV99847782; called by muse, mutect2, varscan2
- RSPH6A | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs774360093, COSV99680133; called by muse, mutect2, varscan2
- RTL8A | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV66188497; called by muse, mutect2, varscan2
- RXFP3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs771228182, COSV57509155; called by muse, mutect2, varscan2
- RYR2 | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as rs564869863, COSV63679506; ClinVar: uncertain significance; called by mutect2, varscan2
- RYR2 | c.9782C>T p.A3261V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs758953445, COSV100773133, COSV63685217; called by muse, varscan2
- RYR3 | c.11062T>G p.S3688A (on ENST00000389232; = p.S3689A on NM_001036.6) | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV101214794; called by muse, mutect2, varscan2
- S100Z | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100461433; called by muse, mutect2, varscan2
- SARM1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776939252, COSV50229827; called by muse, mutect2, varscan2
- SARS1 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52320315, COSV52323683; called by muse, mutect2, varscan2
- SASH1 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV100821484; called by muse, mutect2
- SCAF11 | c.4330C>T p.R1444W | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101014686; called by muse, varscan2
- SDK2 | c.5488G>A p.V1830M | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as rs146597384; called by muse, mutect2, varscan2
- SELENON | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs1291132448, COSV100823590; called by muse, mutect2, varscan2
- SELP | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99741246; called by muse, mutect2, varscan2
- SEMA4D | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs761133169, COSV59396467; called by muse, mutect2, varscan2
- SERPINB2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs553765342, COSV100208711, COSV55094365; called by muse, mutect2, varscan2
- SEZ6L2 | c.2080G>A p.A694T (on ENST00000308713 / NM_001114099.3; = p.A624T on NM_012410.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as rs1246138142; called by muse, mutect2
- SF3B4 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1302218378, COSV99641449; called by muse, mutect2, varscan2
- SFI1 | c.1907G>A p.R636Q (on ENST00000400288 / NM_001007467.3; = p.R605Q on NM_014775.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs751607172, COSV101192318; called by muse, varscan2
- SFPQ | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 316/1260 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1254190174, COSV61759094, COSV61759462; called by muse, mutect2, varscan2
- SGCD | c.606G>T p.E202D (on ENST00000435422 / NM_001128209.2; = p.E203D on NM_000337.5) | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.989); catalogued as COSV100550011, COSV100551270; called by muse, mutect2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV53462966; called by mutect2, varscan2
- SHPRH | c.4093C>T p.R1365C (on ENST00000275233 / NM_001042683.3; = p.R1369C on NM_173082.3) | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378058905, COSV51609268; called by muse, mutect2
- SHTN1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs1050289727, COSV99599505; called by muse, mutect2, varscan2
- SIGLEC10 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as rs201868126; called by muse, mutect2, varscan2
- SIGMAR1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs755288111, COSV99449581, COSV99449617; called by muse, mutect2, varscan2
- SIPA1L2 | c.3554G>A p.G1185D | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99479823; called by muse, mutect2
- SKIDA1 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV101481353; called by muse, mutect2
- SLA | c.398G>A p.R133H (on ENST00000338087 / NM_001045556.3; = p.R173H on NM_006748.4) | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs745463507, COSV55086636; called by muse, mutect2, varscan2
- SLAMF9 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.682); catalogued as rs1398032815, COSV63636697; called by muse, mutect2, varscan2
- SLC11A2 | c.1151A>G p.D384G (on ENST00000394904 / NM_001379455.1; = p.D355G on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs199762460, COSV100015146; called by muse, mutect2, varscan2
- SLC15A4 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs376967004; called by muse, mutect2, varscan2
- SLC16A7 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 171/924 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99676906; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 75/322 reads (23%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC25A24 | c.510+2T>C p.X170_splice | Splice Site (SNP) | VAF 34/208 reads (16%) | catalogued as COSV99916677; called by muse, mutect2, varscan2
- SLC26A11 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV100755474; called by muse, mutect2, varscan2
- SLC28A1 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.21); catalogued as rs1334101396, COSV54476552; called by muse, varscan2
- SLC46A2 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100953483; called by muse, mutect2
- SLC4A3 | c.1220A>C p.D407A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99813279; called by muse, mutect2, varscan2
- SLC4A3 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99812825; called by muse, mutect2, varscan2
- SLC4A3 | c.3176C>T p.A1059V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56097924; called by muse, mutect2, varscan2
- SLC66A3 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 120/1244 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs772145693, COSV99706439; called by muse, mutect2
- SLC6A13 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs537041083, COSV100570094; called by muse, mutect2, varscan2
- SLC6A15 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs139565834; called by muse, mutect2, varscan2
- SLC6A2 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV99574695; called by muse, mutect2, varscan2
- SLC6A5 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs768896174, COSV54227442; called by muse, mutect2, varscan2
- SLC7A3 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.653); catalogued as COSV99979878; called by muse, mutect2, varscan2
- SLC8A1 | c.2546-2A>C p.X849_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100247533; called by muse, mutect2, varscan2
- SLC8A1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1257186367, COSV100247535; called by muse, mutect2, varscan2
- SLC9A2 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 82/852 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.798); catalogued as COSV52129311, COSV99296902; called by muse, mutect2
- SLC9A9 | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100343205; called by muse, varscan2
- SLCO1C1 | c.1046T>G p.L349R | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99860090; called by muse, mutect2
- SLITRK6 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 215/584 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as COSV101233305; called by muse, mutect2, varscan2
- SMOC2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.254); catalogued as rs141002558; called by muse, mutect2, varscan2
- SMPD4 | c.1474C>T p.L492F (on ENST00000409031 / NM_017951.4; = p.L463F on NM_017751.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.971); catalogued as COSV100302817; called by mutect2, varscan2
- SNAP47 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100247873; called by muse, mutect2, varscan2
- SNCA | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV100410257; called by muse, mutect2, varscan2
- SNX10 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs781164071, COSV58401638; called by muse, varscan2
- SNX13 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 259/852 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV101285051; called by muse, mutect2, varscan2
- SNX21 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs781201010, COSV99467883; called by muse, mutect2
- SNX25 | c.1914T>A p.N638K | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99253559; called by mutect2, varscan2
- SNX7 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100069497; called by muse, varscan2
- SOAT2 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100037274; called by muse, mutect2, varscan2
- SOGA3 | c.2537A>G p.Y846C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.783); catalogued as COSV100847088; called by muse, mutect2, varscan2
- SORT1 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99861173; called by muse, mutect2
- SOS1 | c.1785G>T p.K595N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV101217313; called by muse, mutect2, varscan2
- SOS2 | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 46/373 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.565); catalogued as COSV53574922; called by muse, varscan2
- SOX6 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769385306, COSV57035700; called by muse, mutect2, varscan2
- SPAG5 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs1361227462, COSV58804869; called by muse, mutect2, varscan2
- SPATA31E1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100351127; called by muse, mutect2, varscan2
- SPATA6 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 362/1482 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs377106164, COSV64056890; called by muse, mutect2, varscan2
- SPECC1L | c.3121A>G p.N1041D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100063424; called by muse, mutect2, varscan2
- SPEG | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs766108579, COSV56666245; called by muse, mutect2, varscan2
- SPEN | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as rs1178332065, COSV101005645; called by muse, mutect2, varscan2
- SPHKAP | c.5009A>G p.D1670G (on ENST00000392056 / NM_001142644.2; = p.D1641G on NM_030623.3) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100764565; called by muse, mutect2, varscan2
- SPINK4 | c.206T>C p.L69S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV101121889; called by muse, mutect2, varscan2
- SPNS2 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs992178680, COSV99627097; called by muse, mutect2, varscan2
- SPRY3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs775484840, COSV57143637; called by muse, mutect2, varscan2
- SPTB | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1407023521, COSV101071985; called by muse, mutect2, varscan2
- SRF | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99542005; called by muse, mutect2, varscan2
624 further variants in this file (296 protein-altering or splice-affecting, 296 silent, 32 other) are not listed here.
